Gene-level copy-number profile of tumor specimen TCGA-UW-A72J-01A from TCGA case TCGA-UW-A72J, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 43.0 years (15,690 days).
Specimen TCGA-UW-A72J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cfb29993-dc25-4ab8-aebd-cdfe68b62161.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-UW-A72J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/168f27df-2a3c-4365-a505-2e6ea3ef7a6e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 27,760; copy number 2: 30,435; copy number 3: 118; copy number 4: 39; copy number 5: 22.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,589,848, 4 genes: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr8:7,298,744–7,355,359, 5 genes: FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1.
- chr8:12,362,019–12,388,296, 3 genes: FAM66A, AC087203.1, AC087203.2.
- chr8:43,442,902–43,494,762, 2 genes: AC134698.1, AC134698.4.
- chr21:9,975,017–10,137,004, 4 genes: CR382285.1, CR382285.2, CR382287.1, CDRT15P8.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,304,054–22,482,346, 21 genes, copy number 5 (within-gene range 3–5): TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 25,416. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
